Somatic mutation profile of tumor specimen MMRF_1108_1_BM_CD138pos (aliquot MMRF_1108_1_BM_CD138pos_T2_KAS5U_L02449) from MMRF case MMRF_1108, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 85.3 years (31,169 days).
Specimen MMRF_1108_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8872540f-f97b-49ad-889a-4373a8ab8579.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1108_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1108_1_PB_Whole_C3_KAS5U_L02460; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cfe1097-2fe3-47f5-a44d-8b6a41eeb002

The open-access MAF lists 115 somatic variants for this specimen: 58 protein-altering or splice-affecting, 14 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 26, Silent 14, Intron 13, Nonsense Mutation 7, 3'Flank 3, Splice Region 3, Frame Shift Del 3, Splice Site 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- C5orf47 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1252759478; called by muse, mutect2, varscan2
- COL3A1 | c.1930C>A p.P644T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1243924552; called by muse, mutect2, varscan2
- CYP4F22 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs139927884; called by muse, mutect2, varscan2
- DDX55 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769029985, COSV99434920; called by muse, varscan2
- DIS3 | c.1999A>T p.M667L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899945, COSV66707375; called by muse, mutect2, varscan2
- GOLGA2 | c.393_394del p.V133Qfs*10 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs1383001377; called by mutect2, pindel, varscan2
- IGHJ4 | c.3C>G p.Y1* | Nonsense Mutation (SNP) | VAF 31/31 reads (100%) | catalogued as rs368028316; called by muse, varscan2
- IGHV2-70 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs369555797; called by muse, varscan2
- IGHV2-70 | c.8T>G p.I3R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs374765470; called by mutect2, varscan2
- IGKJ3 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 59/128 reads (46%) | catalogued as rs188533155; called by muse, mutect2, varscan2
- IGKJ5 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 84/191 reads (44%) | catalogued as rs375748803; called by muse, mutect2
- IGKV4-1 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 35/37 reads (95%) | catalogued as rs151106836; called by muse, mutect2, varscan2
- IGLV3-1 | c.62A>T p.Y21F | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs145382269; called by muse, varscan2
- IGLV3-1 | c.164A>T p.Q55L | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs543933563; called by muse, varscan2
- KRTAP6-1 | c.49T>G p.F17V | Missense Mutation (SNP) | VAF 153/240 reads (64%) | PolyPhen benign (0.003); catalogued as COSV58168681; called by muse, mutect2, varscan2
- MAP3K19 | c.127A>G p.S43G | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV59641461; called by muse, mutect2, varscan2
- MXRA5 | c.4319C>A p.S1440Y | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.675); catalogued as rs374420182, COSV99476193; called by muse, mutect2, varscan2
- MYO7A | c.6244G>A p.V2082I | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs772912412; called by muse, mutect2, varscan2
- OSBPL6 | c.2650C>T p.R884* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as rs1484638935, COSV51923248; called by muse, mutect2
- PRDM14 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867203929, COSV99400058; called by muse, mutect2
- SRRM1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100105297; called by muse, mutect2, varscan2
- TARS3 | c.2309G>C p.R770T | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60109182; called by muse, mutect2, varscan2
- TRHDE | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV53837299; called by muse, mutect2, varscan2
- ADCY3 | c.3314C>T p.P1105L | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP21 | c.3779A>C p.K1260T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- C3orf14 | c.64A>T p.R22* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- CNOT11 | c.1335+4del | Splice Region (DEL) | VAF 42/122 reads (34%) | called by mutect2, pindel, varscan2
- DSCAML1 | c.1355C>T p.A452V (on ENST00000321322; = p.A392V on NM_020693.4) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DTNBP1 | c.609C>G p.F203L | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- E4F1 | c.1253A>C p.Q418P | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FRK | c.489A>C p.K163N | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GTF2F1 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- IGSF10 | c.7013C>T p.T2338I | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ISCU | c.476C>T p.P159L (on ENST00000311893 / NM_213595.4; = p.P134L on NM_014301.4) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.14); called by muse, mutect2
- KAT6A | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- KDM5B | c.3500T>G p.L1167W | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- LNPEP | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 107/161 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- LRP1B | c.6340A>G p.N2114D | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP2 | c.3551-1G>C p.X1184_splice | Splice Site (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- MCM9 | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NASP | c.1925T>G p.L642R | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKAP | c.1085T>C p.M362T | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PJA2 | c.1265_1266del p.Y422* | Frame Shift Del (DEL) | VAF 42/154 reads (27%) | called by mutect2, pindel, varscan2
- POGLUT3 | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 77/112 reads (69%) | called by muse, mutect2, varscan2
- PPFIA2 | c.1955T>C p.M652T | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PRKCA | c.1619G>C p.G540A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.934); called by muse, mutect2
- RBBP8 | c.2158A>G p.M720V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- RC3H2 | c.1144_1164del p.K382_L388del | In Frame Del (DEL) | VAF 34/62 reads (55%) | called by mutect2, pindel, varscan2
- RSPH9 | c.599C>A p.T200N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SCN1A | c.2996A>C p.N999T (on ENST00000303395 / NM_001202435.3; = p.N988T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SHISA6 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2
- SLC22A14 | c.1391_1392del p.L464Qfs*40 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- THOC7 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- USF3 | c.5319G>C p.Q1773H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.5298+6T>A | Splice Region (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- WAPL | c.2954T>A p.L985* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | called by mutect2, varscan2
- ZNF667 | c.159T>C p.L53= | Splice Region (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2
- CACNA2D1 | c.3090G>T p.L1030= (on ENST00000356253 / NM_001366867.1; = p.L1018= on NM_000722.4) | Silent (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- CD93 | c.1908G>A p.E636= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV55667794; called by muse, mutect2, varscan2
- CEACAM20 | c.45G>C p.L15= | Silent (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- CSMD1 | c.5646G>A p.L1882= (on ENST00000520002; = p.L1881= on NM_033225.6) | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as rs746817185; called by muse, mutect2, varscan2
- HOXC13 | c.795G>C p.V265= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- IGLL5 | c.168T>C p.V56= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1462177154, COSV104440280, COSV104440340; called by muse, varscan2
- KRTAP19-5 | c.141C>T p.G47= | Silent (SNP) | VAF 148/228 reads (65%) | called by muse, mutect2, varscan2
- MYO10 | c.3258C>T p.D1086= | Silent (SNP) | VAF 133/206 reads (65%) | catalogued as rs1488858521; called by muse, mutect2, varscan2
- NYAP2 | c.1335C>T p.S445= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as rs746672929; called by muse, mutect2, varscan2
- SNX19 | c.2673T>A p.P891= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2
- TRPV4 | c.1977G>A p.S659= | Silent (SNP) | VAF 51/113 reads (45%) | called by muse, mutect2, varscan2
- WNT16 | c.177G>A p.L59= (on ENST00000222462 / NM_057168.2; = p.L49= on NM_016087.2) | Silent (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- ZNF320 | c.1386C>T p.I462= | Silent (SNP) | VAF 108/407 reads (27%) | called by muse, mutect2, varscan2
- ZNF850 | c.741T>C p.Y247= | Silent (SNP) | VAF 60/224 reads (27%) | catalogued as rs751877543; called by muse, mutect2, varscan2
- ADAMTS9 | c.5719-77C>T | Intron (SNP) | VAF 98/99 reads (99%) | catalogued as rs970146743; called by muse, mutect2, varscan2
- AKR1B10 | c.*307dup | 3'UTR (INS) | VAF 44/126 reads (35%) | catalogued as rs565285053; called by mutect2, varscan2
- AL450336.1 | n.93A>C | RNA (SNP) | VAF 34/39 reads (87%) | called by muse, mutect2, varscan2
- ALG13 | c.383+3320A>C | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- ATP6V0E2 | c.*140C>A | 3'UTR (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- CARNMT1 | c.*955_*956del | 3'UTR (DEL) | VAF 26/118 reads (22%) | catalogued as rs1302953430; called by pindel, varscan2
- CDH10 | c.*59T>C | 3'UTR (SNP) | VAF 10/261 reads (4%) | called by muse, mutect2
- CEP295 | chr11:93731046 G>C | 3'Flank (SNP) | VAF 32/101 reads (32%) | called by muse, mutect2, varscan2
- CNOT2 | c.1391+963A>T | Intron (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- CTU2 | c.344-132C>G | Intron (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- CYTH1 | c.23-18047C>A | Intron (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- DPT | c.*293G>A | 3'UTR (SNP) | VAF 18/53 reads (34%) | catalogued as rs558300548; called by muse, mutect2, varscan2
- FOXN2 | c.*1691T>C | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- GNAI1 | c.*1060G>C | 3'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- GNS | c.*2983C>G | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- GOLGA7B | c.*547G>A | 3'UTR (SNP) | VAF 37/95 reads (39%) | catalogued as rs190687005; called by muse, varscan2
- GRIN1 | c.2700+83G>A | Intron (SNP) | VAF 47/172 reads (27%) | catalogued as rs1319119082; called by muse, mutect2, varscan2
- HMGB2 | c.*326G>A | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- KLF13 | c.*5181C>T | 3'UTR (SNP) | VAF 34/105 reads (32%) | catalogued as rs558377769; called by muse, mutect2, varscan2
- LRPAP1 | chr4:3500301 G>A | 3'Flank (SNP) | VAF 37/61 reads (61%) | catalogued as rs756538612; called by muse, mutect2, varscan2
- MAP2 | c.*161A>C | 3'UTR (SNP) | VAF 44/75 reads (59%) | called by muse, mutect2, varscan2
- MMRN1 | c.*1183A>T | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- MON2 | c.*2472T>A | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- MST1L | n.1515-70C>A | Intron (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- MYO1B | c.1781+78A>G | Intron (SNP) | VAF 52/111 reads (47%) | catalogued as rs745384254; called by muse, mutect2, varscan2
- NAALAD2 | c.990-57A>C | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- NCOA3 | c.*1870G>A | 3'UTR (SNP) | VAF 24/60 reads (40%) | catalogued as rs541484234; called by muse, mutect2, varscan2
- NOP56 | c.1010+66C>T | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- PATL1 | c.*1263C>T | 3'UTR (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- PBX1 | c.*3391T>C | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- PCDH7 | c.*336G>A | 3'UTR (SNP) | VAF 32/69 reads (46%) | catalogued as rs1434291430; called by muse, mutect2, varscan2
- PSD3 | c.*407A>C | 3'UTR (SNP) | VAF 28/33 reads (85%) | called by muse, mutect2, varscan2
- REG4 | c.*87G>A | 3'UTR (SNP) | VAF 110/150 reads (73%) | catalogued as COSV99858364; called by muse, mutect2, varscan2
- RPRD2 | chr1:150473903 del AG | 3'Flank (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- RPS6KB2 | c.970-35G>C | Intron (SNP) | VAF 167/256 reads (65%) | called by muse, mutect2, varscan2
- SLC25A44 | c.*2293T>G | 3'UTR (SNP) | VAF 23/37 reads (62%) | called by muse, mutect2, varscan2
- SOX5 | c.*1224A>C | 3'UTR (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- TGM3 | c.*488G>A | 3'UTR (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- TSPEAR | c.1566+1750G>A | Intron (SNP) | VAF 11/301 reads (4%) | catalogued as rs587666585; called by muse, mutect2
- TYW3 | c.*561A>G | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- UNC119 | c.611-75C>A | Intron (SNP) | VAF 80/151 reads (53%) | called by muse, mutect2, varscan2
- VAPB | c.*1690C>A | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- ZNF608 | c.*14G>C | 3'UTR (SNP) | VAF 129/428 reads (30%) | called by muse, mutect2, varscan2
